Somatic mutation profile of tumor specimen TARGET-10-PAPLDL-04A (aliquot TARGET-10-PAPLDL-04A-01D) from TARGET case TARGET-10-PAPLDL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.3 years (2,677 days).
Specimen TARGET-10-PAPLDL-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82751661-034d-4c88-9d53-c6ccdc9e3881.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPLDL-10A (Blood Derived Normal), aliquot TARGET-10-PAPLDL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/224b88cf-d542-448e-8528-f069d20f074b

The open-access MAF lists 60 somatic variants for this specimen: 40 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 18, Nonsense Mutation 3, Frame Shift Ins 3, In Frame Ins 2, Splice Region 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR2 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 53/313 reads (17%) | catalogued as rs1060502581, CD1513986, CM043449, COSV65807609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.172A>T p.N58Y | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs397507505, CM044250, CM060441, COSV61007800; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANK3 | c.9689G>A p.R3230H | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs749129953, COSV55059450, COSV55080545; called by muse, mutect2, varscan2
- ANO4 | c.1993G>A p.E665K (on ENST00000392977 / NM_001286615.2; = p.E630K on NM_178826.4) | Missense Mutation (SNP) | VAF 94/220 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54596535; called by muse, mutect2, varscan2
- ANO9 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 23/354 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.261); catalogued as rs757430374, COSV60449455; called by muse, mutect2
- AOC1 | c.1016T>G p.V339G | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV62868775; called by muse, mutect2, varscan2
- CACNA1E | c.2770C>T p.R924C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs757890592, COSV62383300; called by muse, mutect2, varscan2
- CEP112 | c.2414A>T p.Q805L (on ENST00000392769 / NM_001353127.1; = p.Q61L on NM_001037325.3) | Missense Mutation (SNP) | VAF 173/721 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV58064304; called by muse, mutect2, varscan2
- CREB5 | c.542G>A p.G181E (on ENST00000357727 / NM_182898.4; = p.G174E on NM_004904.3) | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63221140; called by muse, mutect2, varscan2
- DYNC2H1 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV62094785; called by muse, mutect2, varscan2
- GDF2 | c.847G>A p.V283M | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs138904328; ClinVar: uncertain significance; called by muse, mutect2
- GLRA2 | c.1021G>A p.V341I | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.939); catalogued as rs767736635, COSV54340983; called by muse, mutect2
- HUWE1 | c.3833G>A p.C1278Y | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV53346452; called by muse, mutect2
- ITGB8 | c.1074G>T p.L358F | Missense Mutation (SNP) | VAF 89/273 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV56009069; called by mutect2, varscan2
- LRP2 | c.3761C>T p.P1254L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV55554543; called by muse, mutect2, varscan2
- NEGR1 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs990499804, COSV60846145, COSV60870999; called by muse, mutect2, varscan2
- PAPPA2 | c.3556G>A p.G1186R | Missense Mutation (SNP) | VAF 87/206 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62791427; called by muse, mutect2, varscan2
- PAX5 | c.328T>A p.F110I | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63907655, COSV63908714; called by muse, mutect2, varscan2
- PCDHGB1 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 11/386 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406977700; called by muse, mutect2
- RMND1 | c.267A>C p.Q89H | Missense Mutation (SNP) | VAF 50/374 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.191); catalogued as COSV60550634; called by muse, mutect2, varscan2
- RRAGD | c.848A>G p.Y283C | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63269122; called by muse, mutect2
- SLC23A3 | c.798G>A p.S266= (on ENST00000409878 / NM_001144889.2; = p.R256Q on NM_144712.5) | Splice Region (SNP) | VAF 10/71 reads (14%) | catalogued as rs560144655, COSV55405875; called by muse, mutect2, varscan2
- SLCO1B3 | c.1084T>G p.Y362D | Missense Mutation (SNP) | VAF 25/443 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53935288, COSV53937948; called by muse, mutect2
- SNX1 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 65/511 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.797); catalogued as COSV56038389, COSV56040344; called by muse, mutect2, varscan2
- SOX6 | c.2125G>A p.E709K (on ENST00000528429 / NM_001145819.2; = p.E682K on NM_017508.3) | Missense Mutation (SNP) | VAF 38/344 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57046547; called by muse, mutect2, varscan2
- SPAST | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 52/383 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59514604; called by muse, mutect2, varscan2
- TAFA4 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55138173; called by muse, mutect2, varscan2
- TRPM1 | c.3820C>T p.R1274* | Nonsense Mutation (SNP) | VAF 53/139 reads (38%) | catalogued as rs761825403, COSV56633639; called by muse, mutect2, varscan2
- ULBP1 | c.602G>A p.W201* | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | catalogued as rs760322129, COSV57664229; called by muse, mutect2, varscan2
- ZC3H4 | c.2209C>T p.P737S | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.32); catalogued as rs1381507058, COSV53413131; called by muse, mutect2, varscan2
- ZNF334 | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 118/325 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV61618783; called by muse, mutect2, varscan2
- ADGRA1 | c.940T>C p.S314P | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.412); called by muse, mutect2
- ARMC6 | c.1002G>A p.M334I (on ENST00000392336; = p.M309I on NM_033415.4) | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- CEP112 | c.2413C>A p.Q805K (on ENST00000392769 / NM_001353127.1; = p.Q61K on NM_001037325.3) | Missense Mutation (SNP) | VAF 174/707 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CUL5 | c.1170_1171insGG p.Q391Gfs*7 | Frame Shift Ins (INS) | VAF 25/205 reads (12%) | called by mutect2, pindel, varscan2
- IGHV4-59 | c.349_350insTCCCCGAG | In Frame Ins (INS) | VAF 8/34 reads (24%) | called by pindel, varscan2
- KMT2D | c.10613_10614insTGACC p.R3539Dfs*121 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- MME | c.354_355insGG p.K119Gfs*13 | Frame Shift Ins (INS) | VAF 58/176 reads (33%) | called by mutect2, pindel, varscan2
- RIT1 | c.245_246insGCC p.F82delinsLP | In Frame Ins (INS) | VAF 26/127 reads (20%) | called by mutect2, pindel, varscan2
- TMEM47 | c.382T>C p.C128R | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANXA5 | c.132C>T p.S44= | Silent (SNP) | VAF 115/311 reads (37%) | catalogued as rs1319728826, COSV56639027; called by muse, mutect2, varscan2
- CEP152 | c.2556C>T p.T852= | Silent (SNP) | VAF 152/417 reads (36%) | catalogued as COSV57859669; called by muse, mutect2, varscan2
- CLEC1B | c.217C>T p.L73= | Silent (SNP) | VAF 191/477 reads (40%) | catalogued as COSV53725553, COSV53726536; called by muse, mutect2, varscan2
- DNAH5 | c.7893G>A p.T2631= | Silent (SNP) | VAF 130/347 reads (37%) | catalogued as rs371810104; called by muse, mutect2, varscan2
- DSG2 | c.2997G>A p.S999= | Silent (SNP) | VAF 65/158 reads (41%) | catalogued as rs763888499, COSV55199347; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAT3 | c.10044G>A p.A3348= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs370318087; called by muse, mutect2, varscan2
- FRAS1 | c.8466C>T p.I2822= | Silent (SNP) | VAF 14/129 reads (11%) | called by muse, mutect2, varscan2
- FSHR | c.1770C>T p.F590= | Silent (SNP) | VAF 35/105 reads (33%) | catalogued as COSV58623618, COSV58624141; called by muse, mutect2, varscan2
- LMO7 | c.3156C>T p.F1052= (on ENST00000357063; = p.F733= on NM_005358.5) | Silent (SNP) | VAF 137/537 reads (26%) | catalogued as rs866212029, COSV58534853, COSV58537906; called by muse, mutect2, varscan2
- MFGE8 | c.570G>T p.A190= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV51556239; called by muse, mutect2
- MYBL2 | c.1320G>A p.T440= | Silent (SNP) | VAF 29/163 reads (18%) | catalogued as rs751255222, COSV53830055; called by muse, mutect2, varscan2
- MYH1 | c.1914G>A p.K638= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as COSV56849001, COSV56849120, COSV99875166; called by muse, mutect2, varscan2
- NLRP5 | c.1626G>A p.R542= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as COSV66764567; called by muse, mutect2, varscan2
- PTPN3 | c.954G>A p.K318= | Silent (SNP) | VAF 122/310 reads (39%) | catalogued as COSV52706162, COSV99355709; called by muse, mutect2, varscan2
- SGTB | c.744C>T p.A248= | Silent (SNP) | VAF 73/179 reads (41%) | catalogued as rs1281689399, COSV66817852; called by muse, mutect2, varscan2
- TMEM132D | c.1149C>T p.I383= | Silent (SNP) | VAF 24/29 reads (83%) | catalogued as COSV70600994; called by muse, mutect2, varscan2
- TUBB2B | c.216G>A p.T72= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as rs752292801, COSV52533729; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF735 | c.1134G>A p.E378= | Silent (SNP) | VAF 50/142 reads (35%) | catalogued as COSV70034934; called by muse, mutect2, varscan2
- APOBEC3B | c.-26G>A | 5'UTR (SNP) | VAF 72/82 reads (88%) | catalogued as rs369907102, COSV100213709; called by muse, mutect2, varscan2
- FAM157A | chr3:198167694 G>A | 5'Flank (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
